MMRF case MMRF_1991 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d34741dd-0474-4897-855e-bb505b350b5d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.7 years (21,441 days); ISS stage: I; Days to last known disease status: 1,004 days (2.7 years); Days to last follow up: 1,004 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 9 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 20 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 516 days (1.4 years); Days to treatment end: 822 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 828 days (2.3 years); Days to treatment end: 871 days (2.4 years).
   Treatment given: Therapeutic agents: Daratumumab + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 876 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 31.9 g/L; Beta 2 Microglobulin 2.63 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.97 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 9.5 g/dL; Glucose 4.95 mmol/L.
- Day 101: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 7.05 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 0.9 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6.65 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 169 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.67 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 7.04 mmol/L.
- Day 261: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 2.02 g/L; Immunoglobulin M 1.12 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.82 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 6.88 mmol/L.
- Day 379 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 3.32 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L.
- Day 507 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 6.34 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.02 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 581 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 6.78 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.47 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.83 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 6.11 mmol/L.
- Day 708 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.33 mmol/L.
- Day 822 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.55 mmol/L.
- Day 914: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 3.96 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.06 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 5.89 mmol/L.
- Day 1,004 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 2.86 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day 0: Weight: 87 kg; Height: 178 cm.

Biospecimens (2 samples)
- Sample MMRF_1991_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1991_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
